MMRF case MMRF_1029 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/6c61647c-968c-4f9a-9136-e984e8484525

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 46 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 46.7 years (17,048 days); ISS stage: I; Days to last known disease status: 995 days (2.7 years); Days to last follow up: 995 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 74 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 84 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 22 days; Days to treatment end: 560 days (1.5 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 85 days; Days to treatment end: 530 days (1.5 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 561 days (1.5 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 561 days (1.5 years); Days to treatment end: 883 days (2.4 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 913 days (2.5 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -4 (ECOG 1): M Protein 1.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.74 mg/dL; Immunoglobulin G 28 g/L; Immunoglobulin A 0.69 g/L; Immunoglobulin M 0.43 g/L; Beta 2 Microglobulin 1.9 µg/mL; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 9.3 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 9.4 g/dL; Glucose 6 mmol/L; C-Reactive Protein 0.27 mg/dL.
- Day 85 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.95 mg/dL; Beta 2 Microglobulin 1.5 µg/mL; Hemoglobin 8.37 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.13 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 6.6 mmol/L.
- Day 141 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.96 mg/dL; Immunoglobulin G 7.26 g/L; Immunoglobulin A 1.5 g/L; Immunoglobulin M 0.4 g/L; Beta 2 Microglobulin 1.4 µg/mL; Lactate Dehydrogenase 3.13 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 11.6 mmol/L.
- Day 247: M Protein 0.3 g/dL; Immunoglobulin G 6.84 g/L; Immunoglobulin A 1.58 g/L; Immunoglobulin M 0.43 g/L; Hemoglobin 9.24 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 13.4 mmol/L.
- Day 365 (ECOG 0): M Protein 0.3 g/dL; Beta 2 Microglobulin 1.2 µg/mL; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.18 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 8.86 mmol/L.
- Day 477: M Protein 0.3 g/dL; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 13 mmol/L.
- Day 561 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.17 mg/dL; Lactate Dehydrogenase 2.08 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.13 mmol/L; Albumin 31 g/L; Total Protein 5.8 g/dL; Glucose 12.8 mmol/L.
- Day 617: M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.45 mg/dL; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.15 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 10.4 mmol/L.
- Day 708 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.24 mg/dL; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 2.1 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 131 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.08 mmol/L; Albumin 37 g/L; Total Protein 5.6 g/dL; Glucose 11.6 mmol/L.
- Day 799: M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.97 mg/dL; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 8.69 mmol/L.
- Day 883 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.5 mg/dL; Lactate Dehydrogenase 3.13 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 7.76 mmol/L.
- Day 995 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.41 mg/dL; Hemoglobin 8.43 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 8.47 mmol/L.

Other clinical attributes
- Day -4: Weight: 126 kg; Height: 182 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Kidney Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1029_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -4 days.
- Sample MMRF_1029_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -4 days.
